Somatic mutation profile of tumor specimen 0DCBJ1 from CCDI case PBBJTG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pineoblastoma; Tissue or organ of origin: Pineal gland; Age at diagnosis: 18.2 years (6,644 days).
Specimen 0DCBJ1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cdf3167a-f62a-40eb-8311-9256ce64ee41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCBIT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4319effb-5491-4044-b9ea-143171aeed9c

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 2, 5'Flank 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.1998G>T p.K666N | Missense Mutation (SNP) | VAF 194/508 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377023736, COSV59205777, COSV59205799; ClinVar: pathogenic / not provided / likely pathogenic; called by mutect2, varscan2
- CABIN1 | c.1399+1G>T p.X467_splice | Splice Site (SNP) | VAF 116/162 reads (72%) | catalogued as COSV54077503; called by muse, mutect2, varscan2
- CD93 | c.1052A>G p.D351G | Missense Mutation (SNP) | VAF 118/311 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs776468245; called by muse, mutect2, varscan2
- AMER1 | c.841C>T p.L281= | Silent (SNP) | VAF 150/358 reads (42%) | called by muse, mutect2, varscan2
- CDH1 | c.378G>A p.P126= | Silent (SNP) | VAF 192/445 reads (43%) | catalogued as rs786201504; ClinVar: likely benign; called by muse, mutect2, varscan2
- ASIC4 | chr2:219514371 C>T | 5'Flank (SNP) | VAF 102/266 reads (38%) | catalogued as rs999936803; called by muse, mutect2, varscan2
- ZDHHC11 | c.-70C>T | 5'UTR (SNP) | VAF 24/61 reads (39%) | catalogued as rs1053277883; called by muse, mutect2, varscan2
